Somatic mutation profile of tumor specimen 150c2086-1815-40d2-bc5d-8eeb48 (aliquot 150c2086-1815-40d2-bc5d-8eeb48_D6_2) from CPTAC case 09BR005, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 38.7 years (14,143 days).
Specimen 150c2086-1815-40d2-bc5d-8eeb48: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43f03972-8aaf-4799-9a6e-fffa5980b606.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen fb2f019d-a181-4939-916a-5dccbd (Blood Derived Normal), aliquot fb2f019d-a181-4939-916a-5dccbd_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ccead3e-0204-4e33-a475-8f21dd659b07

The open-access MAF lists 98 somatic variants for this specimen: 62 protein-altering or splice-affecting, 20 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Intron 10, Splice Site 3, Frame Shift Del 3, In Frame Del 2, Frame Shift Ins 2, 3'UTR 2, Nonsense Mutation 2, RNA 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 247/474 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV50772159, COSV99180119; called by muse, mutect2, varscan2
- AHRR | c.1082A>T p.D361V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs769124578; called by muse, mutect2, varscan2
- AKR1C2 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 111/416 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs782385243; called by muse, mutect2, varscan2
- AP5B1 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 178/497 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745327454; called by muse, mutect2, varscan2
- BBS12 | c.1996_1998del p.V666del | In Frame Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs779685329; called by pindel, varscan2
- CYP19A1 | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 94/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99547444; called by muse, mutect2, varscan2
- FGD5 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs369779761; called by muse, mutect2, varscan2
- GLIS3 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 145/402 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1407324725, COSV60923714; called by muse, mutect2, varscan2
- IQGAP3 | c.4475A>T p.Q1492L | Missense Mutation (SNP) | VAF 90/450 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as rs1213616202; called by muse, mutect2, varscan2
- LAPTM4B | c.773C>G p.T258S (on ENST00000445593; = p.T167S on NM_018407.6) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs946052294; called by muse, mutect2, varscan2
- MANF | c.334_336del p.K112del | In Frame Del (DEL) | VAF 59/190 reads (31%) | catalogued as rs782449001; called by pindel, varscan2
- MCIDAS | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs747069505; called by muse, mutect2, varscan2
- NYNRIN | c.4009C>T p.P1337S | Missense Mutation (SNP) | VAF 120/296 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs371735612; called by muse, mutect2, varscan2
- OR13H1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 100/312 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.215); catalogued as COSV58548213; called by muse, mutect2, varscan2
- OR51E1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs146565220; called by muse, mutect2
- SAMD9L | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV59083111; called by muse, mutect2, varscan2
- SMTN | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs769867394, COSV100293847; called by muse, mutect2, varscan2
- STAB2 | c.6336G>C p.K2112N | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.906); catalogued as COSV101186465; called by muse, mutect2
- TBX1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs956393764; called by muse, mutect2, varscan2
- TLN2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60891869, COSV60896194; called by muse, mutect2
- WASF2 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71005016; called by muse, mutect2, varscan2
- WNT3A | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 124/397 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52729560; called by muse, mutect2, varscan2
- ATXN1 | c.1312_1315dup p.S439Tfs*61 | Frame Shift Ins (INS) | VAF 124/396 reads (31%) | called by mutect2, varscan2
- C9 | c.59del p.T20Kfs*12 | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | called by mutect2, pindel, varscan2
- CLPX | c.1655G>C p.R552T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCC | c.50T>G p.L17R | Missense Mutation (SNP) | VAF 118/378 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ETV3 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM189B | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 349/603 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by mutect2, varscan2
- FAM98A | c.203-2del p.X68_splice | Splice Site (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.2359+2T>C p.X787_splice | Splice Site (SNP) | VAF 70/189 reads (37%) | called by muse, mutect2, varscan2
- GATA4 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 190/622 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, varscan2
- GPR162 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 11/224 reads (5%) | called by muse, mutect2
- GPRASP2 | c.1758C>A p.C586* | Nonsense Mutation (SNP) | VAF 100/273 reads (37%) | called by muse, mutect2, varscan2
- GRXCR1 | c.674A>T p.D225V | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HERC1 | c.13567G>A p.D4523N | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HERC6 | c.879T>A p.D293E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HNRNPDL | c.309del p.A104Rfs*20 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by mutect2, pindel, varscan2
- IGFBP3 | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- KIF20B | c.2987_2988insCGTTCTCTTGA p.S997Vfs*12 (on ENST00000371728 / NM_001284259.2; = p.S957Vfs*12 on NM_016195.4) | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, varscan2
- KLHL38 | c.851A>G p.D284G | Missense Mutation (SNP) | VAF 148/477 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2E | c.3491_3495del p.K1164Tfs*3 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1372A>T p.T458S | Missense Mutation (SNP) | VAF 131/423 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTTP | c.2343-38_2348del p.X781_splice | Splice Site (DEL) | VAF 51/254 reads (20%) | called by mutect2, pindel, varscan2
- MUC17 | c.10619C>G p.T3540S | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- NOS2 | c.2497G>C p.D833H | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ODF3L2 | c.533C>G p.P178R | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PI4KA | c.3437G>A p.R1146H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PKN2 | c.1967A>G p.D656G | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- PLXND1 | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 145/435 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RPSA | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC20A2 | c.1333A>T p.I445F | Missense Mutation (SNP) | VAF 166/474 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SLC7A3 | c.1788C>A p.N596K | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM229B | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TMEM245 | c.2134G>C p.D712H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- TNRC18 | c.7291C>A p.P2431T | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TRANK1 | c.5300G>A p.C1767Y | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UBE2N | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS33A | c.928G>C p.V310L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WIPF2 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 504/1271 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZDHHC17 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZMYND11 | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AC138647.1 | c.180G>T p.A60= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1213681060, COSV70194637; called by mutect2, varscan2
- ADAMTS8 | c.2151C>T p.D717= | Silent (SNP) | VAF 59/124 reads (48%) | catalogued as rs527937005; called by muse, mutect2, varscan2
- AGBL2 | c.306C>T p.G102= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, varscan2
- B3GALNT2 | c.396C>T p.S132= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs140100348; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA2D2 | c.3336C>T p.R1112= (on ENST00000479441 / NM_001174051.3; = p.R1105= on NM_006030.4) | Silent (SNP) | VAF 66/230 reads (29%) | catalogued as rs186468159; ClinVar: likely benign; called by muse, mutect2, varscan2
- CARNS1 | c.1881C>T p.S627= | Silent (SNP) | VAF 133/408 reads (33%) | catalogued as rs751514911, COSV57050832; called by muse, mutect2, varscan2
- KCNA5 | c.1494G>A p.S498= | Silent (SNP) | VAF 152/364 reads (42%) | catalogued as rs576837393, COSV52905200; called by muse, mutect2, varscan2
- LNX1 | c.1089C>T p.S363= (on ENST00000263925 / NM_001126328.3; = p.S267= on NM_032622.2) | Silent (SNP) | VAF 22/338 reads (7%) | called by muse, mutect2
- OR13J1 | c.627A>G p.V209= | Silent (SNP) | VAF 212/684 reads (31%) | called by muse, mutect2, varscan2
- PKD1 | c.5913G>C p.V1971= | Silent (SNP) | VAF 99/287 reads (34%) | catalogued as CD1210687; called by muse, mutect2, varscan2
- PPP1R3A | c.2484T>C p.P828= | Silent (SNP) | VAF 114/377 reads (30%) | called by muse, mutect2, varscan2
- RBP2 | c.120G>C p.T40= | Silent (SNP) | VAF 70/189 reads (37%) | catalogued as COSV51674789; called by muse, mutect2, varscan2
- RELN | c.3882C>A p.T1294= | Silent (SNP) | VAF 63/200 reads (32%) | catalogued as COSV100634259; called by muse, mutect2, varscan2
- RTN3 | c.1200A>G p.K400= (on ENST00000377819 / NM_001265589.2; = p.K381= on NM_201428.3) | Silent (SNP) | VAF 49/133 reads (37%) | called by muse, mutect2, varscan2
- SBK1 | c.741C>T p.L247= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- SF3B3 | c.996T>A p.T332= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV100209884; called by muse, mutect2, varscan2
- SOX11 | c.1179G>A p.S393= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as rs1384690500, COSV58984034; called by muse, mutect2, varscan2
- TGIF2LX | c.219G>T p.R73= | Silent (SNP) | VAF 149/514 reads (29%) | called by muse, mutect2, varscan2
- TPTE | c.1098G>A p.L366= (on ENST00000618007 / NM_199261.4; = p.L348= on NM_199259.4) | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1451165323; called by muse, mutect2
- WARS2 | c.402T>G p.P134= | Silent (SNP) | VAF 39/113 reads (35%) | called by muse, mutect2, varscan2
- AC002511.3 | n.164A>G | RNA (SNP) | VAF 58/162 reads (36%) | catalogued as rs763873145; called by muse, mutect2, varscan2
- ALOX12B | c.651-84A>C | Intron (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- CSMD2 | c.1326+5903A>G | Intron (SNP) | VAF 45/492 reads (9%) | catalogued as rs1045210721; called by muse, mutect2
- CYP4A11 | c.1364+10C>A | Intron (SNP) | VAF 66/211 reads (31%) | called by muse, mutect2, varscan2
- DHRS4-AS1 | n.3046T>A | RNA (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- HSF4 | c.485+44C>T | Intron (SNP) | VAF 10/166 reads (6%) | catalogued as rs1356206092; called by muse, mutect2
- KRI1 | c.169-19A>T | Intron (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- KRT14 | c.609-17C>A | Intron (SNP) | VAF 161/316 reads (51%) | called by muse, mutect2, varscan2
- MDM1 | c.134-482A>C | Intron (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- MEF2A | c.390+186C>T | Intron (SNP) | VAF 25/83 reads (30%) | catalogued as rs376743625; called by muse, mutect2, varscan2
- NXPE1 | c.834-916G>C | Intron (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- PDCD6IP | c.835-788C>A | Intron (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- RAB18 | c.*816C>T | 3'UTR (SNP) | VAF 50/142 reads (35%) | called by muse, mutect2, varscan2
- TFF2 | c.*87T>G | 3'UTR (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- TVP23A | c.-8G>T | 5'UTR (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- USP15 | chr12:62258730 G>C | 5'Flank (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
